Gene-level copy-number profile of tumor specimen HCM-SANG-1325-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-1325-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1325-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2fb1216c-b325-415e-9256-7c80c7a63b40.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1325-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/0a41644c-b0de-40d2-ac43-214d27b0323b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 189; copy number 1: 48; copy number 2: 5,207; copy number 3: 541; copy number 4: 41,158; copy number 5: 312; copy number 6: 6,261; copy number 7: 626; copy number 8: 2,984; copy number 9: 1,039; copy number 10: 25; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 148 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:166,195,185–166,376,001, 1 gene (within-gene range 0–2): SCN9A.
- chr3:3,700,814–5,256,761, 25 genes (within-gene range 0–2): SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1.
- chr4:178,685,886–178,685,956, 1 gene: AC017087.1.
- chr5:26,012,889–27,121,150, 9 genes (within-gene range 0–2): RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P.
- chr5:104,773,641–104,799,772, 2 genes (within-gene range 0–2): AC099520.2, RNU6-334P.
- chr6:165,279,664–165,309,605, 1 gene: C6orf118.
- chr6:165,409,562–165,409,676, 1 gene (within-gene range 0–2): RNA5SP226.
- chr7:126,438,598–127,253,093, 8 genes (within-gene range 0–6): GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1, MIR592, GRM8-AS1.
- chr8:12,628,476–17,002,345, 51 genes: RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, RN7SL474P, FGF20.
- chr8:34,784,028–36,321,404, 15 genes: LINC01288, AC087343.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:43,442,902–43,674,591, 9 genes: AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:21,695,176–22,128,103, 16 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:30,388,935–30,575,012, 2 genes (within-gene range 0–2): LINC01242, SLC4A1APP1.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.
- chr17:22,671,433–22,706,703, 3 genes: AC131274.3, AC131274.1, AC131274.2.
- chr18:51,158,282–51,283,896, 3 genes: SRSF10P1, MEX3C, RNU1-46P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,065 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:205,681,990–206,314,427, 25 genes, copy number 10: NRP2, AC007362.1, RN7SKP178, PPIAP68, AC007679.1, INO80D, Vault, Y_RNA, RPL27P8, AC007383.1, NDUFS1, AC007383.2, GCSHP3, EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41, GPR1, GPR1-AS, RN7SKP200, ATP5POP1, HMGN1P6, RN7SKP260, ZDBF2.
- chr7:37,032–10,239,863, 213 genes, copy number 9–14 (broad region; genes not listed).
- chr7:10,451,311–10,476,878, 2 genes, copy number 9: HSPA8P8, AC009945.1.
- chr7:12,211,270–31,708,455, 320 genes, copy number 9 (broad region; genes not listed).
- chr7:32,485,338–63,088,261, 488 genes, copy number 9 (broad region; genes not listed).
- chr7:65,335,174–65,859,766, 17 genes, copy number 9: RSL24D1P3, AC092685.1, ZNF92, AC114501.3, AC114501.1, AC114501.2, AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P.

Autosomal genes at a single copy (total copy number 1): 48. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
